TCGA case TCGA-AF-2689 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/335d0351-3740-4847-9ff4-be2f078c70f7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Dead; Days to death: 1,201 days (3.3 years).

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 41.3 years (15,082 days); Year of diagnosis: 2009; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,201 days (3.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 32; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Palliative; Days to treatment start: 85 days; Days to treatment end: 239 days; Number of cycles: 10; Treatment dose: 2,364 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Palliative; Days to treatment start: 85 days; Days to treatment end: 269 days; Number of cycles: 12; Treatment dose: 42,192 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Palliative; Days to treatment start: 85 days; Days to treatment end: 267 days; Number of cycles: 12; Treatment dose: 7,032 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Palliative; Days to treatment start: 85 days; Days to treatment end: 267 days; Number of cycles: 12; Treatment dose: 7,200 mg; Prescribed dose: 600; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Palliative; Days to treatment start: 85 days; Days to treatment end: 267 days; Number of cycles: 11; Treatment dose: 707 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Clinical Trial; Initial disease status: Progressive Disease; Days to treatment start: 316 days; Days to treatment end: 344 days; Number of cycles: 3; Treatment dose: 537 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 316 days; Days to treatment end: 346 days; Number of cycles: 3; Treatment dose: 10,296 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 316 days; Days to treatment end: 344 days; Number of cycles: 3; Treatment dose: 1,716 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 316 days; Days to treatment end: 344 days; Number of cycles: 3; Treatment dose: 772 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 316 days; Days to treatment end: 344 days; Number of cycles: 3; Treatment dose: 1,716 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Floxuridine + Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 379 days (1.0 years); Days to treatment end: 559 days (1.5 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 379 days (1.0 years); Days to treatment end: 559 days (1.5 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 462 days (1.3 years); Days to treatment end: 559 days (1.5 years); Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.1 years (15,383 days); Days to diagnosis: 301 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.6 years (15,543 days); Days to diagnosis: 461 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 44.4 years (16,216 days); Days to diagnosis: 1,134 days (3.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.

Follow-up (6 entries)
- Day 301 (post initial treatment): Progression or recurrence: Yes.
- Day 461 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 482 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 546 days (1.5 years); Disease response: With Tumor.
- Day 1,134 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,201 days (3.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 6 ng/mL.
- KRAS mutation, nos: Positive; Mutation codon: 13.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 55.5 kg; Height: 163 cm; BMI: 20.9.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AF-2689-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-AF-2689-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-AF-2689-01A-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
- Sample TCGA-AF-2689-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AF-2689-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-AF-2689-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 6.0; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: 5FU; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 1; Pharmaceutical therapy drug name: Aflibercept/ Placebo Study; Therapy regimen: Progression.
- Drug treatment 11: Regimen number: 2; Pharmaceutical therapy drug name: Camptosar; Therapy regimen: Progression.
- Drug treatment 12: Regimen number: 2; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 13: Regimen number: 2; Pharmaceutical therapy drug name: FUDR (Floxuridine); Therapy regimen: Progression.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 3, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,201 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,201 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 301 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AF-2689-01A-01D-1549-01): tumor purity 0.62, ploidy 3.25, whole-genome doublings 1.
